Somatic mutation profile of tumor specimen 0DU4VG from CCDI case PBCJNP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.4 years (131 days).
Specimen 0DU4VG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38f82880-343c-44f9-9494-82603c907680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU4V3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1973c639-1cd2-4a50-9e20-7194b7fb558a

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP4K1 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 35/922 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs1421857461, COSV67712269; called by muse, mutect2
- TERB1 | c.642G>A p.T214= | Silent (SNP) | VAF 151/2772 reads (5%) | catalogued as rs77610148, COSV100509215; called by muse, mutect2
- CCDC102B | c.1263+41C>T | Intron (SNP) | VAF 57/2517 reads (2%) | catalogued as rs1381078244; called by muse, mutect2
